Somatic mutation profile of tumor specimen HCM-BROD-0209-C71-02A (aliquot HCM-BROD-0209-C71-02A-11D-A786-36) from HCMI case HCM-BROD-0209-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 41.8 years (15,280 days).
Specimen HCM-BROD-0209-C71-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec18c89a-65b2-4f15-8251-254703a3d905.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0209-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0209-C71-10A-01D-A786-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a01ba487-3fef-4737-a03b-8f255b79a248

The open-access MAF lists 105 somatic variants for this specimen: 67 protein-altering or splice-affecting, 21 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 21, 5'UTR 5, Frame Shift Del 4, Intron 3, RNA 3, Splice Site 3, Nonsense Mutation 2, 3'Flank 2, 3'UTR 2, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIF26B | c.6071G>A p.R2024H | Missense Mutation (SNP) | VAF 48/155 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs199933797, COSV63638897; called by muse, mutect2, varscan2
- RB1 | c.1421+1G>C p.X474_splice | Splice Site (SNP) | VAF 27/41 reads (66%) | hotspot (GDC flag); catalogued as rs1131690886, COSV57295416, COSV57303849, COSV57308621; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 151/241 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADPRHL1 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.817); catalogued as rs774381207, COSV100733595; called by muse, mutect2, varscan2
- ALDH3B2 | c.737C>T p.T246M | Missense Mutation (SNP) | VAF 68/221 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.223); catalogued as rs111503561; called by muse, mutect2, varscan2
- CAPN6 | c.1558A>C p.I520L | Missense Mutation (SNP) | VAF 117/143 reads (82%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as rs747889694; called by muse, mutect2, varscan2
- CHRNA9 | c.992G>A p.R331Q | Missense Mutation (SNP) | VAF 62/190 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.025); catalogued as rs1479555056, COSV59575340; called by muse, mutect2, varscan2
- COL1A1 | c.2449C>T p.P817S | Missense Mutation (SNP) | VAF 138/347 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs769167761; called by muse, mutect2, varscan2
- DENND5B | c.1993A>G p.T665A | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs770983656; called by muse, varscan2
- DSP | c.6442G>A p.A2148T | Missense Mutation (SNP) | VAF 69/252 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs144539278, COSV65794417; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DTX3 | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 70/185 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV99677817; called by muse, mutect2, varscan2
- FAM163A | c.52C>T p.L18F | Missense Mutation (SNP) | VAF 89/224 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1403683637; called by muse, mutect2, varscan2
- FRMPD4 | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 106/149 reads (71%) | SIFT deleterious (0); PolyPhen benign (0.311); catalogued as COSV101043402; called by muse, mutect2, varscan2
- MAP7 | c.229C>T p.R77W | Missense Mutation (SNP) | VAF 45/255 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763941595; called by muse, mutect2, varscan2
- MARCHF4 | c.1004G>C p.R335P | Missense Mutation (SNP) | VAF 127/279 reads (46%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.763); catalogued as COSV56105119, COSV56108597; called by muse, mutect2, varscan2
- MSH4 | c.1330C>T p.P444S | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.018); catalogued as rs757262974; called by muse, mutect2, varscan2
- NCOA5 | c.1708G>A p.A570T | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.109); catalogued as rs1484342220; called by mutect2, varscan2
- NLRP5 | c.1384C>T p.R462C | Missense Mutation (SNP) | VAF 125/374 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.731); catalogued as rs199475775, COSV66767095; ClinVar: not provided; called by muse, mutect2, varscan2
- OR51G1 | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs764009160; called by muse, mutect2, varscan2
- PHLDB2 | c.3506G>A p.R1169Q (on ENST00000393925 / NM_001134439.2; = p.R1126Q on NM_145753.2) | Missense Mutation (SNP) | VAF 13/207 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.777); catalogued as rs140319291; called by muse, mutect2
- PIEZO2 | c.7016G>A p.R2339H | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99555018; called by muse, mutect2
- POM121L12 | c.302C>A p.A101D | Missense Mutation (SNP) | VAF 99/253 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.308); catalogued as COSV68692154; called by muse, mutect2, varscan2
- PRKCQ | c.97G>A p.V33I | Missense Mutation (SNP) | VAF 146/203 reads (72%) | SIFT tolerated (0.44); PolyPhen benign (0.144); catalogued as rs372791078; called by muse, mutect2, varscan2
- PTEN | c.98T>A p.I33N | Missense Mutation (SNP) | VAF 33/52 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV64289312, COSV64292633; called by muse, mutect2, varscan2
- SCN11A | c.4685G>A p.R1562Q | Missense Mutation (SNP) | VAF 62/142 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs771220857, COSV56565664, COSV56573959; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRPV5 | c.1519G>A p.A507T | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1051550257; called by muse, mutect2
- TRPV6 | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV63892156; called by muse, mutect2, varscan2
- UNC13A | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 44/178 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.249); catalogued as rs566299244, COSV53210618; called by muse, varscan2
- YES1 | c.575-1G>T p.X192_splice | Splice Site (SNP) | VAF 9/44 reads (20%) | catalogued as COSV58848418; called by muse, mutect2, varscan2
- ZNF558 | c.885C>G p.H295Q | Missense Mutation (SNP) | VAF 36/193 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as COSV100038013; called by muse, mutect2, varscan2
- ZNF844 | c.1370C>T p.S457L | Missense Mutation (SNP) | VAF 90/298 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.1); catalogued as rs746107574; called by muse, mutect2, varscan2
- ABCC12 | c.1624A>G p.T542A | Missense Mutation (SNP) | VAF 44/269 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- ADGRB3 | c.4394C>T p.P1465L | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ADGRG6 | c.2861A>G p.H954R | Missense Mutation (SNP) | VAF 48/343 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANGPTL1 | c.1127A>G p.D376G | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD18B | c.733T>A p.L245M | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- CDHR2 | c.1976del p.G659Afs*5 | Frame Shift Del (DEL) | VAF 79/435 reads (18%) | called by mutect2, pindel, varscan2
- DCLK3 | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- DGAT2 | c.994A>G p.K332E | Missense Mutation (SNP) | VAF 54/240 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- DISP1 | c.3562G>T p.E1188* | Nonsense Mutation (SNP) | VAF 181/451 reads (40%) | called by muse, mutect2, varscan2
- DNAH12 | c.4930G>A p.E1644K (on ENST00000351747; = p.E1667K on NM_001366028.2) | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- DNAH3 | c.11071+2T>A p.X3691_splice | Splice Site (SNP) | VAF 19/85 reads (22%) | called by muse, mutect2, varscan2
- GSTA4 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 63/258 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- KEL | c.1954A>T p.R652W | Missense Mutation (SNP) | VAF 16/557 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2
- KIAA1614 | c.2458G>A p.V820M | Missense Mutation (SNP) | VAF 42/220 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KPNA1 | c.277T>C p.S93P | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MAML1 | c.1292del p.Q431Rfs*10 | Frame Shift Del (DEL) | VAF 33/95 reads (35%) | called by mutect2, pindel, varscan2
- MAP1B | c.751T>C p.S251P | Missense Mutation (SNP) | VAF 39/152 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MBD4 | c.856del p.R286Efs*17 | Frame Shift Del (DEL) | VAF 129/457 reads (28%) | called by mutect2, pindel, varscan2
- MYO1D | c.1045G>C p.E349Q | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- NHEJ1 | c.896G>C p.S299T | Missense Mutation (SNP) | VAF 144/299 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- NXF3 | c.1571A>G p.E524G | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- OR6Q1 | c.871C>T p.P291S | Missense Mutation (SNP) | VAF 36/239 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PNPLA6 | c.3515A>G p.D1172G (on ENST00000414982 / NM_001166111.2; = p.D1124G on NM_006702.5) | Missense Mutation (SNP) | VAF 92/462 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- POGLUT3 | c.1351C>A p.L451I | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- PPP1R15B | c.445T>A p.W149R | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- RPF2 | c.698A>G p.D233G | Missense Mutation (SNP) | VAF 68/154 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- SDK1 | c.3853G>A p.A1285T | Missense Mutation (SNP) | VAF 99/324 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- TENM2 | c.1185A>G p.I395M (on ENST00000518659 / NM_001122679.2; = p.I204M on NM_001080428.3) | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- TNNI3 | c.10G>T p.G4W | Missense Mutation (SNP) | VAF 34/253 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- TRAF7 | c.926A>G p.D309G | Missense Mutation (SNP) | VAF 99/630 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UHMK1 | c.1005del p.N336Mfs*9 (on ENST00000489294 / NM_175866.5; = p.N336Mfs*55 on NM_144624.2) | Frame Shift Del (DEL) | VAF 52/123 reads (42%) | called by mutect2, pindel, varscan2
- UNC5C | c.311A>G p.D104G | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- XCL2 | c.14T>C p.I5T | Missense Mutation (SNP) | VAF 102/273 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF334 | c.127T>C p.Y43H | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- ZNF462 | c.1820A>G p.Y607C | Missense Mutation (SNP) | VAF 73/359 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- ZNF667 | c.1378G>T p.E460* | Nonsense Mutation (SNP) | VAF 38/110 reads (35%) | called by muse, mutect2, varscan2
- CNTNAP4 | c.1680C>T p.H560= | Silent (SNP) | VAF 55/144 reads (38%) | catalogued as rs779366718; called by muse, mutect2, varscan2
- DHX37 | c.1302C>T p.S434= | Silent (SNP) | VAF 65/172 reads (38%) | catalogued as rs950622312; called by muse, mutect2, varscan2
- DNAH6 | c.6156A>T p.R2052= | Silent (SNP) | VAF 110/262 reads (42%) | called by muse, mutect2, varscan2
- EGF | c.192C>A p.T64= | Silent (SNP) | VAF 54/155 reads (35%) | catalogued as rs367667834; ClinVar: likely benign; called by muse, mutect2, varscan2
- FMN1 | c.1539A>G p.T513= | Silent (SNP) | VAF 77/202 reads (38%) | catalogued as rs771538811; called by muse, mutect2, varscan2
- FRAS1 | c.387A>G p.P129= | Silent (SNP) | VAF 111/564 reads (20%) | called by muse, mutect2, varscan2
- HOXA2 | c.99A>G p.Q33= | Silent (SNP) | VAF 108/733 reads (15%) | called by muse, mutect2, varscan2
- ITGA4 | c.1278G>A p.S426= | Silent (SNP) | VAF 27/70 reads (39%) | catalogued as rs201581651, COSV52001707, COSV99275884; called by muse, mutect2, varscan2
- LINGO2 | c.837C>T p.N279= | Silent (SNP) | VAF 37/177 reads (21%) | called by muse, mutect2, varscan2
- LRP1B | c.4965A>G p.A1655= | Silent (SNP) | VAF 30/66 reads (45%) | called by muse, mutect2, varscan2
- MAVS | c.744A>G p.V248= | Silent (SNP) | VAF 58/292 reads (20%) | catalogued as rs752018252; called by muse, mutect2, varscan2
- MUC17 | c.9453T>C p.G3151= | Silent (SNP) | VAF 33/316 reads (10%) | called by muse, mutect2, varscan2
- OTOP1 | c.294G>A p.A98= | Silent (SNP) | VAF 64/498 reads (13%) | called by muse, mutect2
- PHF3 | c.915T>C p.G305= | Silent (SNP) | VAF 19/62 reads (31%) | called by muse, mutect2, varscan2
- RELL2 | c.264C>T p.A88= | Silent (SNP) | VAF 52/189 reads (28%) | called by muse, mutect2, varscan2
- SCN5A | c.141C>T p.P47= | Silent (SNP) | VAF 101/284 reads (36%) | catalogued as rs571894716; ClinVar: likely benign; called by muse, mutect2, varscan2
- TMEM88B | c.285C>T p.C95= | Silent (SNP) | VAF 24/88 reads (27%) | called by muse, mutect2, varscan2
- TNS4 | c.573C>G p.P191= | Silent (SNP) | VAF 37/241 reads (15%) | catalogued as COSV54188972; called by muse, mutect2, varscan2
- TRGV9 | c.222T>C p.Y74= | Silent (SNP) | VAF 78/540 reads (14%) | catalogued as rs755717159; called by muse, mutect2, varscan2
- TTYH2 | c.90G>T p.V30= | Silent (SNP) | VAF 52/406 reads (13%) | called by muse, mutect2, varscan2
- UBR5 | c.3237G>A p.K1079= | Silent (SNP) | VAF 11/66 reads (17%) | called by muse, mutect2, varscan2
- AC002511.3 | chr19:35408563 C>A | 3'Flank (SNP) | VAF 41/308 reads (13%) | called by muse, mutect2, varscan2
- ALB | c.-13C>T | 5'UTR (SNP) | VAF 72/191 reads (38%) | catalogued as rs369763404; called by muse, mutect2, varscan2
- BLOC1S5-TXNDC5 | c.372+38522C>G | Intron (SNP) | VAF 82/177 reads (46%) | called by muse, mutect2, varscan2
- C11orf40 | n.397C>T | RNA (SNP) | VAF 73/150 reads (49%) | catalogued as rs772223493; called by muse, mutect2, varscan2
- CR1 | c.487+11993G>A | Intron (SNP) | VAF 221/516 reads (43%) | called by muse, mutect2, varscan2
- GLTPP1 | chr11:18188945 C>T | 5'Flank (SNP) | VAF 71/294 reads (24%) | catalogued as rs1380117276; called by muse, mutect2, varscan2
- HERC2P3 | n.1119G>A | RNA (SNP) | VAF 136/625 reads (22%) | catalogued as rs753822098; called by muse, mutect2, varscan2
- HOOK1 | c.-40_-37delinsGTT | 5'UTR (DEL) | VAF 27/220 reads (12%) | called by mutect2*, pindel, varscan2*
- MLIP | c.-1T>C | 5'UTR (SNP) | VAF 16/108 reads (15%) | called by muse, mutect2, varscan2
- PABPC1P2 | n.690G>T | RNA (SNP) | VAF 97/204 reads (48%) | catalogued as rs753648140; called by muse, mutect2, varscan2
- PLEKHM1 | c.*983G>A | 3'UTR (SNP) | VAF 43/134 reads (32%) | called by muse, mutect2, varscan2
- RALGDS | c.*41T>G | 3'UTR (SNP) | VAF 117/246 reads (48%) | catalogued as rs772780500; called by muse, mutect2, varscan2
- RNU6-389P | chr7:55687839 C>T | 3'Flank (SNP) | VAF 72/428 reads (17%) | catalogued as rs757960757; called by muse, mutect2, varscan2
- SOHLH1 | c.-29G>A | 5'UTR (SNP) | VAF 157/320 reads (49%) | catalogued as rs745716133; called by muse, mutect2, varscan2
- TESC | c.-127G>A | 5'UTR (SNP) | VAF 24/56 reads (43%) | called by muse, mutect2, varscan2
- TTC6 | chr14:37792327 G>A | 5'Flank (SNP) | VAF 37/54 reads (69%) | catalogued as rs556874303; called by muse, mutect2, varscan2
- ZEB2 | c.73+4999T>G | Intron (SNP) | VAF 53/193 reads (27%) | called by muse, mutect2, varscan2
